Somatic mutation profile of tumor specimen TCGA-24-2033-01A (aliquot TCGA-24-2033-01A-01W-0722-08) from TCGA case TCGA-24-2033, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 87.5 years (31,977 days).
Specimen TCGA-24-2033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 936ebe65-d133-4985-91ea-1f0636fd3bae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2033-10A (Blood Derived Normal), aliquot TCGA-24-2033-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff9c6297-9ab0-4b88-adda-6febe72cad34

The open-access MAF lists 121 somatic variants for this specimen: 91 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 26, Nonsense Mutation 9, Frame Shift Del 4, 5'Flank 2, In Frame Del 2, RNA 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- A1BG | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.195); catalogued as COSV99568648; called by muse, mutect2, varscan2
- ABCB4 | c.3805C>A p.Q1269K (on ENST00000265723 / NM_018849.3; = p.Q1262K on NM_000443.4) | Missense Mutation (SNP) | VAF 200/566 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99711204; called by muse, mutect2, varscan2
- ABCF1 | c.1811G>A p.R604H (on ENST00000326195 / NM_001025091.2; = p.R566H on NM_001090.3) | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs766316432, COSV58228983, COSV58229219; called by muse, mutect2, varscan2
- ACACB | c.6186G>C p.Q2062H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV100623261; called by muse, mutect2, varscan2
- ACBD6 | c.497G>C p.C166S | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100852571; called by muse, mutect2, varscan2
- ACTR5 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99710216; called by muse, mutect2, varscan2
- ADAMTS19 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 291/1177 reads (25%) | catalogued as COSV50735929, COSV99180420; called by muse, mutect2, varscan2
- AFF4 | c.2796+1G>C p.X932_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99535356; called by muse, mutect2
- ANO3 | c.1217T>A p.L406* | Nonsense Mutation (SNP) | VAF 272/948 reads (29%) | catalogued as COSV99885445; called by muse, mutect2, varscan2
- AP3B1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99672383; called by muse, mutect2, varscan2
- ARHGEF39 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100526346; called by muse, mutect2, varscan2
- BAD | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.099); catalogued as COSV100464479; called by muse, mutect2, varscan2
- BTBD3 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1005150840, COSV54777784; called by muse, mutect2, varscan2
- CBLC | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99542277; called by muse, mutect2, varscan2
- CD1B | c.641G>A p.S214N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV63804223; called by muse, mutect2, varscan2
- CFAP54 | c.5843T>G p.I1948R | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100733311; called by muse, mutect2, varscan2
- CHORDC1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100272164; called by muse, mutect2, varscan2
- CLDN8 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); catalogued as rs778908212, COSV54527935; called by muse, mutect2, varscan2
- CNTNAP5 | c.1808T>A p.F603Y | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101444177; called by muse, mutect2, varscan2
- CTNND1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 107/503 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100650263; called by muse, mutect2, varscan2
- CXCR1 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1469888447, COSV99826409; called by muse, varscan2
- DNAH5 | c.8340A>T p.K2780N | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV54204725; called by muse, mutect2, varscan2
- DUXA | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV101617156; called by muse, mutect2, varscan2
- EDAR | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV99304195; called by muse, mutect2, varscan2
- EGFL8 | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as rs745371156, COSV100247080; called by muse, mutect2, varscan2
- EPHA8 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99385635; called by muse, mutect2, varscan2
- ERICH3 | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 124/667 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs77857865, COSV100445579; called by muse, mutect2, varscan2
- EZH2 | c.1689A>T p.K563N (on ENST00000460911 / NM_001203247.2; = p.K568N on NM_004456.5) | Missense Mutation (SNP) | VAF 118/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100236673; called by muse, mutect2, varscan2
- FAM135B | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99358067; called by muse, mutect2, varscan2
- FRMD6 | c.17T>A p.F6Y | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV100656258; called by muse, mutect2, varscan2
- FRMD6 | c.1206G>T p.K402N (on ENST00000344768 / NM_001267046.2; = p.K394N on NM_152330.4) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV100656261; called by muse, mutect2, varscan2
- GABRA1 | c.1268C>A p.S423* | Nonsense Mutation (SNP) | VAF 47/215 reads (22%) | catalogued as COSV50110354, COSV99067045; called by muse, mutect2, varscan2
- GAD1 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100713922; called by muse, mutect2, varscan2
- GALNT5 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 116/261 reads (44%) | catalogued as COSV99375571; called by muse, mutect2, varscan2
- GRIK2 | c.1875G>T p.E625D | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.996); catalogued as COSV100029124; called by muse, mutect2, varscan2
- H2BC13 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100704433; called by muse, mutect2, varscan2
- HECA | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 29/632 reads (5%) | catalogued as COSV100866254; called by muse, mutect2
- HLA-E | c.845T>G p.V282G | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100931985; called by muse, mutect2, varscan2
- HTR1D | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs202033009, COSV100025050; called by muse, mutect2, varscan2
- INSRR | c.1924T>C p.W642R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs372272702, COSV100948044; called by muse, mutect2, varscan2
- ITGA2 | c.1091T>A p.I364N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs201859025, COSV99671532; called by muse, mutect2, varscan2
- ITPR1 | c.7616T>G p.L2539R (on ENST00000354582; = p.L2484R on NM_002222.7) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100233050; called by muse, mutect2, varscan2
- LIMK1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs1554695664, COSV60284794; called by muse, mutect2, varscan2
- LIPE | c.2425G>C p.V809L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs138009253; called by muse, mutect2
- LIPJ | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs764992748, COSV100905927; called by muse, mutect2
- ME3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100661107; called by muse, mutect2, varscan2
- MMP27 | c.1491G>C p.L497F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV99498670; called by muse, mutect2, varscan2
- MYORG | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV52626468; called by muse, mutect2, varscan2
- NRCAM | c.994G>T p.E332* (on ENST00000379028 / NM_001371124.1; = p.E326* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 59/294 reads (20%) | catalogued as COSV100695415; called by muse, mutect2, varscan2
- OBSCN | c.12238G>C p.E4080Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV52767103, COSV99483847; called by muse, mutect2, varscan2
- PCDHB3 | c.768del p.V257Lfs*13 | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | catalogued as COSV50638754; called by mutect2, pindel, varscan2
- PCLO | c.9062C>G p.T3021R | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100427491, COSV100437244; called by muse, mutect2, varscan2
- PDZD2 | c.5902G>A p.G1968R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99226562; called by muse, mutect2, varscan2
- PKHD1L1 | c.12266C>A p.P4089Q | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV101006765, COSV65741277; called by muse, mutect2
- PRPF4B | c.2651C>G p.T884S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV100528368, COSV61783216; called by muse, mutect2, varscan2
- PTGER3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100139605; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2220G>C p.W740C | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99921700; called by muse, mutect2, varscan2
- RPL23A | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1567752892; called by muse, mutect2
- RPRD2 | c.1561A>G p.I521V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as COSV100955348; called by muse, mutect2, varscan2
- SATB2 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746319722, COSV53488971; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SCEL | c.1229T>A p.L410H (on ENST00000349847 / NM_144777.3; = p.L390H on NM_003843.4) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583200; called by muse, mutect2, varscan2
- SHKBP1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs1203695526, COSV52540731; called by muse, mutect2, varscan2
- SLC25A31 | c.861T>A p.N287K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139762125; called by muse, mutect2, varscan2
- SLC28A1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99723495; called by muse, mutect2, varscan2
- SLC30A5 | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV101173647; called by muse, mutect2, varscan2
- SLC35A3 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100924707; called by muse, varscan2
- SLC41A2 | c.1409A>T p.Q470L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99316894; called by muse, mutect2, varscan2
- SLC6A2 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99574577; called by muse, mutect2, varscan2
- SPHK2 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as COSV99320382; called by muse, mutect2, varscan2
- STAG1 | c.3550C>T p.H1184Y | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.316); catalogued as COSV99366851; called by muse, mutect2, varscan2
- STK31 | c.998A>C p.Q333P | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV100669908; called by muse, mutect2, varscan2
- THNSL1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750985721, COSV100896303; called by muse, mutect2, varscan2
- THSD7A | c.3306G>T p.E1102D | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV101448880; called by muse, mutect2, varscan2
- THSD7A | c.964G>T p.G322* | Nonsense Mutation (SNP) | VAF 85/412 reads (21%) | catalogued as COSV101448881; called by muse, mutect2, varscan2
- TMEM266 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101189651; called by muse, mutect2, varscan2
- TRIP13 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 107/739 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV99386534; called by muse, mutect2, varscan2
- TTN | c.26783T>A p.L8928* (on ENST00000591111; = p.L8001* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100628150; called by muse, mutect2, varscan2
- UBE3C | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as COSV100780077; called by muse, mutect2, varscan2
- ZCWPW2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs760348222, COSV101075253; called by muse, mutect2, varscan2
- ZDBF2 | c.6064G>C p.G2022R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100985489; called by muse, varscan2
- ZNF106 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV99783130; called by muse, mutect2, varscan2
- ZNF582 | c.43T>G p.F15V | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100018931; called by muse, mutect2, varscan2
- ASXL1 | c.2670_2693del p.V891_W898del | In Frame Del (DEL) | VAF 34/176 reads (19%) | called by mutect2, pindel*
- BIRC6 | c.10057_10068del p.A3353_A3356del | In Frame Del (DEL) | VAF 136/803 reads (17%) | called by mutect2, pindel, varscan2
- FBXO34 | c.47dup p.E17Gfs*19 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by pindel, varscan2
- FCGRT | c.1073_1074dup p.N359* | Frame Shift Ins (INS) | VAF 47/400 reads (12%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.4257_4282del p.P1420Tfs*13 | Frame Shift Del (DEL) | VAF 66/249 reads (27%) | called by mutect2, pindel
- MROH1 | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TBC1D23 | c.162del p.W54* | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- ZCCHC7 | c.766_775del p.C256Hfs*54 | Frame Shift Del (DEL) | VAF 36/69 reads (52%) | called by mutect2, pindel, varscan2
- ACHE | c.792T>C p.N264= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99574526; called by muse, mutect2
- ANKFY1 | c.1224A>C p.A408= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100493131; called by muse, mutect2, varscan2
- BCAT2 | c.996G>A p.V332= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as COSV100302548; called by muse, mutect2, varscan2
- CC2D1A | c.1653C>T p.A551= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as rs370966628; called by muse, mutect2
- CIZ1 | c.2382G>C p.V794= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99477115; called by muse, mutect2, varscan2
- CRY1 | c.1392T>A p.V464= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV99151063; called by muse, mutect2, varscan2
- CSMD3 | c.1827C>T p.G609= (on ENST00000297405 / NM_001363185.1; = p.G505= on NM_052900.3) | Silent (SNP) | VAF 78/478 reads (16%) | catalogued as rs765801232, COSV52209744, COSV52314232; called by muse, mutect2, varscan2
- CTC1 | c.597G>A p.T199= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs373023392, COSV59852406; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CXCR1 | c.951C>G p.L317= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as COSV99826411; called by muse, varscan2
- DIS3L2 | c.1299C>T p.S433= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs752632643, COSV56066766; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLYR1 | c.588G>C p.P196= | Silent (SNP) | VAF 90/381 reads (24%) | catalogued as COSV100424525, COSV58926091; called by muse, mutect2, varscan2
- GNAS | c.363T>G p.P121= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV58336448; called by muse, mutect2
- HNRNPL | c.1134C>T p.H378= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs766793183, COSV99670543; called by muse, mutect2, varscan2
- HTR1A | c.219T>C p.Y73= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100109262; called by muse, mutect2, varscan2
- IFNA17 | c.159G>A p.L53= | Silent (SNP) | VAF 120/524 reads (23%) | catalogued as COSV101303470; called by muse, mutect2, varscan2
- KLF7 | c.48C>G p.V16= | Silent (SNP) | VAF 53/203 reads (26%) | catalogued as COSV100518874, COSV100519368; called by muse, mutect2, varscan2
- LILRB3 | c.222A>C p.P74= | Silent (SNP) | VAF 59/444 reads (13%) | catalogued as rs1392578105; called by muse, mutect2
- NEBL | c.2109G>A p.E703= | Silent (SNP) | VAF 88/359 reads (25%) | catalogued as COSV101009343; called by muse, mutect2, varscan2
- PLAA | c.1077G>A p.G359= | Silent (SNP) | VAF 81/328 reads (25%) | catalogued as COSV101263562; called by muse, mutect2, varscan2
- PTPRK | c.3888C>G p.P1296= (on ENST00000368215 / NM_001291984.2; = p.P1297= on NM_002844.4) | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV100951543; called by muse, mutect2, varscan2
- SLC9A1 | c.801C>T p.D267= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs1426836194, COSV99849993; called by muse, mutect2, varscan2
- SORL1 | c.3078C>T p.C1026= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99495336; called by mutect2, varscan2
- TIGD7 | c.858C>T p.D286= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs148242088; called by muse, mutect2, varscan2
- TP53BP2 | c.3261A>G p.G1087= (on ENST00000343537 / NM_001031685.3; = p.G958= on NM_005426.2) | Silent (SNP) | VAF 61/221 reads (28%) | catalogued as COSV100636792; called by muse, mutect2, varscan2
- WNT10B | c.390C>T p.H130= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs371021990; called by muse, mutect2, varscan2
- WNT7A | c.339C>T p.A113= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs148842161; called by muse, mutect2, varscan2
- AGAP7P | n.941A>G | RNA (SNP) | VAF 50/193 reads (26%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848888 G>A | 5'Flank (SNP) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- NXF5 | n.423G>A | RNA (SNP) | VAF 174/678 reads (26%) | catalogued as COSV99534638; called by muse, mutect2, varscan2
- S100A5 | chr1:153541395 G>T | 5'Flank (SNP) | VAF 27/216 reads (13%) | catalogued as COSV100573148; called by muse, mutect2, varscan2
